Gene-level copy-number profile of tumor specimen MP2PRT-PATUHM-TMP1-A from MP2PRT case MP2PRT-PATUHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.4 years (499 days).
Specimen MP2PRT-PATUHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53fe18d0-a784-4a0b-9bb0-24cf2d9fe809.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATUHM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/f7344804-f5d6-41c1-80e9-fcf05d590e18

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23,240; copy number 1: 1,390; copy number 2: 40; copy number 3: 149; copy number 4: 27,662; copy number 5: 2; copy number 6: 78; copy number 7: 3,743; copy number 8: 2,562; copy number 12: 41.

Caution: 22,729 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 22,729 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–10,982,037, 145 genes (broad region; genes not listed).
- chr1:12,507,246–248,937,043, 4,889 genes (within-gene range 0–1) (broad region; genes not listed).
- chr2:30,146,941–30,187,566, 2 genes: YPEL5, SNORA10B.
- chr2:89,170,775–89,245,596, 10 genes (within-gene range 0–3): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr2:90,159,840–90,160,335, 1 gene (within-gene range 0–1): IGKV1D-12.
- chr2:90,179,889–90,210,529, 3 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43.
- chr3:11,745–198,123,232, 3,100 genes (broad region; genes not listed).
- chr7:2,679,522–38,230,670, 576 genes (broad region; genes not listed).
- chr7:38,335,041–142,470,013, 1,876 genes (within-gene range 0–2) (broad region; genes not listed).
- chr7:142,796,365–142,797,502, 8 genes (within-gene range 0–1): TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7.
- chr7:142,812,586–159,233,377, 338 genes (broad region; genes not listed).
- chr9:12,134–126,507,041, 1,831 genes (broad region; genes not listed).
- chr10:63,222,155–63,223,045, 1 gene (within-gene range 0–4): TATDN1P1.
- chr13:18,609,132–114,337,626, 1,327 genes (broad region; genes not listed).
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–12): TRDD1, TRDD2, TRDD3, TRDJ1.
- chr15:19,878,555–101,979,093, 2,192 genes (broad region; genes not listed).
- chr16:3,181,233–15,139,339, 304 genes (within-gene range 0–1) (broad region; genes not listed).
- chr16:15,395,754–90,222,851, 1,918 genes (within-gene range 0–1) (broad region; genes not listed).
- chr19:186,373–42,740,481, 1,872 genes (broad region; genes not listed).
- chr19:42,821,863–58,605,223, 1,073 genes (within-gene range 0–1) (broad region; genes not listed).
- chr20:87,250–61,083,750, 1,259 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 41 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,924,063–22,418,657, 40 genes, copy number 12 (within-gene range 7–12): TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3.
- chr14:22,547,506–22,552,156, 1 gene, copy number 12: TRAC.

Autosomal genes at a single copy (total copy number 1): 1,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
